TARGET case TARGET-30-PASLCD — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6573a7e-690f-5537-a15e-25edba479684

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 3.2 years (1,166 days); Year of diagnosis: 2009; Days to last follow up: 3,419 days (9.4 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 3; Mitosis karyorrhexis index: High.
   Pathology details: Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ALTE03N1.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: D9902.
   Treatment given: Protocol identifier: ANBL0531.

Follow-up (2 entries)
- Days to follow up: 661 days (1.8 years); Days to first event: 661 days (1.8 years); First event: Second Malignant Neoplasm.
- Days to follow up: 3,419 days (9.4 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASLCD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PASLCD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3419
- Protocol: ANBL00B1, ANBL0531, ANBL0532, ANBL0032, D9902, ALTE03N1
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.11
- Histology: Unfavorable
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
